Somatic mutation profile of tumor specimen MP2PRT-PAUWBZ-TMP1-A (aliquot MP2PRT-PAUWBZ-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUWBZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,125 days).
Specimen MP2PRT-PAUWBZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a45f404-eab0-45db-a7e2-8cab4f333929.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUWBZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUWBZ-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab53ef81-aa80-4a48-b65a-39e0e2e37bc6

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H2BC5 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 54/674 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV56799699, COSV56799726; called by muse, mutect2
- MYH10 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV52597202; called by muse, mutect2, varscan2
- SRSF2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 199/706 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV57972402; called by muse, mutect2, varscan2
- H4C8 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- IGHV2-70 | c.356_358delinsCCCCCT p.I119delinsTP | In Frame Ins (INS) | VAF 77/228 reads (34%) | called by pindel, varscan2*
- LRRC70 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP91 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 144/476 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NSD2 | c.1992C>A p.A664= | Silent (SNP) | VAF 93/305 reads (30%) | called by muse, mutect2, varscan2
- TMED7 | c.264G>A p.E88= | Silent (SNP) | VAF 23/271 reads (8%) | catalogued as rs750645927; called by muse, mutect2
- YWHAB | c.120C>T p.N40= | Silent (SNP) | VAF 134/450 reads (30%) | catalogued as rs766591292; called by muse, mutect2, varscan2
- PPP1CC | c.882+21G>C | Intron (SNP) | VAF 50/506 reads (10%) | called by muse, mutect2
